Gene-level copy-number profile of tumor specimen C3N-03764-02 from CPTAC case C3N-03764, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 69.1 years (25,223 days).
Specimen C3N-03764-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file c2e638ea-a8d2-4b75-8618-0b29dda3d552.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03764-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/6bdf1356-9e49-424f-88eb-ef39002fa5d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 325; copy number 1: 3,352; copy number 2: 23,898; copy number 3: 13,461; copy number 4: 16,620; copy number 5: 821; copy number 6: 303; copy number 7: 123; copy number 8: 8; copy number 11: 3.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,502,145–49,508,806, 2 genes: ANKRD20A17P, AC119751.5.
- chr5:87,205,408–87,412,930, 5 genes (within-gene range 0–2): LINC01949, RASA1, RN7SL629P, RNU6-606P, CCNH.
- chr8:12,356,136–12,414,373, 6 genes: ZNF705CP, FAM66A, AC087203.1, AC087203.2, DEFB109A, AC087203.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,258 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:138,901,433–139,379,147, 2 genes, copy number 5: AHCYP4, AC062021.1.
- chr5:58,198–28,214,559, 413 genes, copy number 6–11 (broad region; genes not listed).
- chr7:38,239,580–38,330,935, 15 genes, copy number 7 (within-gene range 4–7): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8.
- chr14:18,343,038–18,343,144, 1 gene, copy number 6: RNU6-458P.
- chr14:18,418,775–18,419,273, 1 gene, copy number 5: BNIP3P6.
- chr19:31,149,979–46,471,563, 728 genes, copy number 5 (broad region; genes not listed).
- chr20:25,919,499–32,585,074, 84 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:45,293,445–45,348,424, 4 genes, copy number 5: MATN4, RBPJL, SDC4, AL021578.1.
- chr21:10,413,477–13,067,033, 10 genes, copy number 5–6: BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 809. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
